CCDI case PBCBNA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/9361926d-275d-4c24-83a2-d7396789ca99

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Spindle cell rhabdomyosarcoma: ICD-O-3 morphology code: 8912/3; Tissue or organ of origin: Liver; Age at diagnosis: 3.8 years (1,382 days).

Biospecimens (3 samples)
- Sample 0DNJA4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNJAV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNJBA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
